TCGA case TCGA-06-0397 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/28bf7388-f041-4ff6-ba70-4dcfa05805a3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 274 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 57.1 years (20,845 days); Year of diagnosis: 1993; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Days to treatment start: 104 days; Days to treatment end: 115 days; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine + Procarbazine + Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 126 days; Days to treatment end: 176 days; Number of cycles: 2.
2. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tumor of origin: diagnosis 1 of this record; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 20 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 168 days; Disease response: With Tumor.
- Days to follow up: 274 days; Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.4; Intermediate dimension: 0.3; Shortest dimension: 0.2.
  Slide TCGA-06-0397-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
  Slide TCGA-06-0397-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Preoperative.
- Radiation treatment: Radiation type other: Sterotactic Radiosurgery.
- Follow-up form, New tumor event: New tumor event type: Locoregional Disease; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 274 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 274 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 274 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-06-0397-01): tumor purity 0.78, ploidy 2.11, whole-genome doublings 0 (call status: legacy_call).
